CCDI case PBBSME — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2309bf60-2c52-4f83-bdac-6f698b09fe1a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,013 days).

Biospecimens (3 samples)
- Sample 0DFRTZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFRU1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
